Somatic mutation profile of tumor specimen TCGA-86-7955-01A (aliquot TCGA-86-7955-01A-11D-2184-08) from TCGA case TCGA-86-7955, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 62.3 years (22,772 days).
Specimen TCGA-86-7955-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d6406ce-6b98-4890-85bc-5fdbb524ddfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-7955-10A (Blood Derived Normal), aliquot TCGA-86-7955-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e864a4d-37e6-437e-a7e2-4a46b13c4ac2

The open-access MAF lists 341 somatic variants for this specimen: 257 protein-altering or splice-affecting, 74 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 74, Nonsense Mutation 20, Frame Shift Del 7, Intron 7, Splice Site 3, Frame Shift Ins 3, In Frame Del 3, Translation Start Site 2, RNA 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMNA | c.1526dup p.T510Yfs*42 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | catalogued as rs58013325; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.426_458del p.V143_P153del | In Frame Del (DEL) | VAF 28/56 reads (50%) | hotspot (GDC flag); called by mutect2, pindel
- ABCA5 | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.87); catalogued as rs763638212, COSV67017916; called by muse, mutect2, varscan2
- ABCB1 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99713699; called by muse, mutect2, varscan2
- ABCB8 | c.271G>T p.V91F (on ENST00000297504 / NM_001282291.2; = p.V74F on NM_007188.5) | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV99874766; called by muse, varscan2
- ABCF2 | c.874T>A p.C292S | Missense Mutation (SNP) | VAF 113/352 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99734712; called by muse, mutect2, varscan2
- ACAN | c.5393A>G p.Q1798R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV100718790; called by muse, mutect2, varscan2
- ACSS3 | c.1619C>G p.A540G | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99699236; called by muse, mutect2, varscan2
- ADAL | c.651dup p.E218Rfs*11 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs778831705; called by mutect2, varscan2
- ADAMTS2 | c.1039T>A p.Y347N | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as COSV99202605; called by muse, mutect2, varscan2
- ADCY8 | c.1888G>T p.D630Y | Missense Mutation (SNP) | VAF 92/111 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV53914571, COSV99653398; called by muse, mutect2, varscan2
- AFTPH | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV99481017; called by muse, mutect2, varscan2
- AKAP13 | c.6408G>T p.R2136S (on ENST00000394518 / NM_007200.5; = p.R2140S on NM_006738.6) | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100774229; called by muse, mutect2, varscan2
- AKR7A2 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99352131; called by muse, mutect2, varscan2
- ANKRD50 | c.3011A>T p.D1004V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV101539004; called by muse, mutect2, varscan2
- AOAH | c.1290C>A p.N430K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99333345; called by muse, varscan2
- ARHGAP30 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs903282972, COSV100920166; called by muse, mutect2
- ARID4A | c.376A>T p.T126S | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100794512; called by muse, mutect2, varscan2
- ARNTL | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 126/171 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724694; called by muse, mutect2, varscan2
- ASH1L | c.3808C>G p.R1270G | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100853532, COSV100853534; called by muse, mutect2, varscan2
- ATP13A5 | c.233C>A p.T78K | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100664965; called by muse, mutect2
- B3GALT1 | c.455T>A p.L152H | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002950; called by muse, mutect2, varscan2
- B4GALNT3 | c.1979C>G p.S660C | Missense Mutation (SNP) | VAF 122/185 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773231973, COSV99843364; called by muse, mutect2, varscan2
- BMT2 | c.1154G>C p.G385A | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.22); catalogued as COSV99774762; called by muse, mutect2, varscan2
- CARD11 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs367917190, COSV62754973; called by muse, mutect2, varscan2
- CCAR1 | c.1201T>A p.W401R | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99771245; called by muse, mutect2, varscan2
- CCAR1 | c.1202G>T p.W401L | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99771247; called by muse, mutect2, varscan2
- CCDC178 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100285834; called by muse, mutect2, varscan2
- CCDC40 | c.2935C>A p.R979S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100884295, COSV100884364; called by muse, mutect2, varscan2
- CCDC51 | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 22/29 reads (76%) | catalogued as COSV99603163; called by muse, mutect2, varscan2
- CD163 | c.2456C>A p.S819* | Nonsense Mutation (SNP) | VAF 67/143 reads (47%) | catalogued as COSV100776011; called by muse, mutect2, varscan2
- CDH10 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.478); catalogued as COSV100052408, COSV52573731, COSV52585721; called by muse, mutect2, varscan2
- CDH2 | c.902A>G p.N301S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs374009883; called by muse, mutect2, varscan2
- CHRM2 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57781690; called by muse, mutect2, varscan2
- CNTN5 | c.3265T>A p.L1089M | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV99679413; called by muse, mutect2
- COL9A3 | c.1669G>T p.G557C | Missense Mutation (SNP) | VAF 191/278 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100102344; called by muse, mutect2, varscan2
- CPA4 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99745221; called by muse, mutect2, varscan2
- CRY2 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314560; called by muse, mutect2, varscan2
- CSAD | c.181C>T p.R61W (on ENST00000444623 / NM_001244705.2; = p.R88W on NM_015989.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1323083299, COSV57243886; called by muse, mutect2
- CSNK2A1 | c.427-1G>T p.X143_splice | Splice Site (SNP) | VAF 45/82 reads (55%) | catalogued as COSV53937885; called by muse, mutect2, varscan2
- CTBP1 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV99337963; called by muse, mutect2, varscan2
- CXorf21 | c.381A>T p.L127F | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100973332; called by muse, mutect2, varscan2
- CYP4F2 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV99171106; called by muse, mutect2, varscan2
- DCC | c.2553G>T p.Q851H | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100501859; called by muse, mutect2, varscan2
- DCC | c.2554G>T p.A852S | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100501861, COSV59081303; called by muse, mutect2, varscan2
- DDB1 | c.1893G>C p.L631F | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100074754; called by muse, mutect2, varscan2
- DEFB115 | c.133T>C p.C45R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101269322; called by muse, mutect2, varscan2
- DGKB | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99341767; called by muse, mutect2, varscan2
- DGKG | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99403870; called by muse, mutect2, varscan2
- DHX34 | c.1930A>T p.T644S | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100169769; called by muse, mutect2, varscan2
- DLG1 | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 89/115 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV100015721; called by muse, mutect2, varscan2
- DLG2 | c.1018T>A p.Y340N | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.288); catalogued as COSV99718040; called by muse, mutect2, varscan2
- DNAAF2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs758890955, COSV100024209; called by muse, mutect2, varscan2
- DNAH5 | c.1753A>G p.I585V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs760809036, COSV99452185; called by muse, mutect2, varscan2
- DNAH8 | c.1444C>A p.R482S | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.77); PolyPhen benign (0.115); catalogued as rs765078483, COSV100546553, COSV59428926; called by muse, mutect2, varscan2
- DNAJC10 | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 75/121 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99899476; called by muse, mutect2, varscan2
- DPP6 | c.1200C>A p.N400K (on ENST00000377770 / NM_001364500.2; = p.N338K on NM_001936.5) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100127012, COSV100127630; called by muse, mutect2, varscan2
- DRC1 | c.1196G>A p.W399* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as rs533192395, COSV56537322, COSV99985213; called by muse, mutect2, varscan2
- EFHC1 | c.1225G>T p.V409F | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100932100, COSV64135959; called by muse, mutect2, varscan2
- EFHD2 | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1333614894, COSV101044427; called by muse, mutect2, varscan2
- EGFLAM | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.129); catalogued as rs374589503, COSV59307379; called by muse, mutect2, varscan2
- EGR1 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1158530364, COSV99525541; called by muse, mutect2, varscan2
- EIF4G3 | c.4640A>G p.Y1547C | Missense Mutation (SNP) | VAF 277/417 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99945077; called by muse, mutect2, varscan2
- EMC10 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618523; called by muse, mutect2, varscan2
- EPHA5 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV56639209, COSV99900172; called by muse, mutect2, varscan2
- ERN2 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV99891978; called by muse, mutect2, varscan2
- EVC2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV100186456; called by muse, mutect2, varscan2
- EXTL3 | c.1951C>G p.Q651E | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV99593806, COSV99594202, COSV99594299; called by muse, mutect2, varscan2
- FADS6 | c.443C>A p.T148K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100044323; called by muse, mutect2, varscan2
- FAM126A | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV101300017; called by muse, mutect2, varscan2
- FGF6 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 68/131 reads (52%) | catalogued as COSV99960352; called by muse, mutect2, varscan2
- FJX1 | c.1055T>A p.M352K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.492); catalogued as COSV100502729; called by muse, mutect2, varscan2
- FLG | c.8638G>T p.G2880W | Missense Mutation (SNP) | VAF 108/793 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100911879; called by muse, mutect2, varscan2
- FLNC | c.6049G>T p.V2017L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV100368458, COSV57966956; called by muse, mutect2, varscan2
- FOLH1 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1356470952, COSV99923589; called by muse, mutect2
- FSD1 | c.894G>T p.Q298H | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV99696928; called by muse, mutect2, varscan2
- FSD1 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55696676, COSV99696931; called by muse, mutect2, varscan2
- FTHL17 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 99/113 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV100784366; called by muse, mutect2, varscan2
- GABRB3 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 61/185 reads (33%) | catalogued as COSV100160990; called by muse, mutect2, varscan2
- GABRG1 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV54959245, COSV99778480; called by muse, mutect2, varscan2
- GCC2 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV100565563; called by muse, mutect2, varscan2
- GCC2 | c.3316G>C p.E1106Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV100565564; called by muse, mutect2, varscan2
- GFPT1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100622936, COSV61946987; called by muse, mutect2, varscan2
- GJC2 | c.49C>A p.H17N | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100812977; called by muse, mutect2, varscan2
- GLB1 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 47/62 reads (76%) | catalogued as rs1295295164, COSV100257568; called by muse, mutect2, varscan2
- GOLGA4 | c.3056C>T p.S1019L | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100729051; called by muse, mutect2, varscan2
- GPLD1 | c.1466T>A p.F489Y | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs776739194, COSV100015480; called by muse, mutect2, varscan2
- GPR139 | c.655C>G p.R219G | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV100429961; called by muse, mutect2, varscan2
- GPR158 | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.599); catalogued as COSV100894033, COSV66282154; called by muse, mutect2, varscan2
- GPR32 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99567307; called by muse, mutect2, varscan2
- GRB10 | c.1105G>T p.V369F (on ENST00000398812; = p.V323F on NM_001001549.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as COSV100240809; called by muse, mutect2, varscan2
- GRIA2 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 65/86 reads (76%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.989); catalogued as COSV52404163, COSV99646099; called by muse, mutect2, varscan2
- GRM5 | c.1882G>T p.G628C | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.685); catalogued as COSV59627861; called by muse, mutect2, varscan2
- GRSF1 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99635876; called by muse, mutect2, varscan2
- H4C3 | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV100619609; called by muse, mutect2, varscan2
- HAVCR2 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100324884; called by muse, mutect2, varscan2
- HECW2 | c.2497A>T p.T833S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99648144; called by muse, mutect2, varscan2
- HECW2 | c.1732A>G p.S578G | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1208909460, COSV99648145; called by muse, mutect2, varscan2
- HIVEP3 | c.6210G>T p.R2070S | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56020698, COSV99913401; called by muse, mutect2, varscan2
- HSPA13 | c.954G>C p.R318S | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99580184; called by muse, mutect2, varscan2
- IBTK | c.3419A>T p.K1140M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100091150; called by muse, mutect2, varscan2
- IGKV2D-29 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101534390; called by muse, mutect2, varscan2
- INO80 | c.2131G>T p.E711* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100731979; called by muse, mutect2
- IRX2 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121836; called by muse, mutect2, varscan2
- ITCH | c.884C>G p.T295R (on ENST00000262650 / NM_001257137.3; = p.T254R on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV99392917; called by muse, mutect2, varscan2
- ITGA11 | c.1877C>A p.A626D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV100241946; called by muse, mutect2, varscan2
- KCNA4 | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100069137; called by muse, varscan2
- KCNC2 | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs143215099, COSV100129974; called by muse, mutect2, varscan2
- KCNC2 | c.1408C>G p.P470A | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100129475, COSV100129709; called by muse, mutect2, varscan2
- KCNU1 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 67/74 reads (91%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV101299357; called by muse, mutect2, varscan2
- KL | c.1914G>T p.W638C | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101199170; called by muse, mutect2, varscan2
- KPNA5 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV100706344; called by muse, mutect2, varscan2
- LELP1 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 61/203 reads (30%) | catalogued as COSV100907355; called by muse, mutect2, varscan2
- LRP5 | c.4550A>T p.Y1517F | Missense Mutation (SNP) | VAF 186/264 reads (70%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV99592399; called by muse, mutect2, varscan2
- LRRIQ3 | c.733del p.Q245Sfs*16 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs375424853; called by pindel, varscan2
- LRRK1 | c.2810T>G p.I937S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99441805; called by muse, mutect2, varscan2
- LTO1 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs1279820656, COSV99654164; called by muse, mutect2, varscan2
- LYZL1 | c.427G>T p.A143S (on ENST00000375500; = p.A97S on NM_032517.6) | Missense Mutation (SNP) | VAF 131/251 reads (52%) | SIFT tolerated (0.99); PolyPhen benign (0.095); catalogued as COSV100973664; called by muse, mutect2, varscan2
- MAGEL2 | c.3670G>T p.E1224* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100046097; called by muse, mutect2, varscan2
- MAP3K19 | c.2552C>A p.P851H | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.781); catalogued as COSV100208963; called by muse, mutect2, varscan2
- MAPKBP1 | c.3771G>C p.K1257N (on ENST00000456763 / NM_001128608.2; = p.K1251N on NM_014994.3) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs757384488, COSV52966610; called by muse, mutect2, varscan2
- MCAM | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50644539; called by muse, mutect2, varscan2
- MED20 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV99539931; called by muse, mutect2, varscan2
- MEIS2 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 122/306 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as COSV99576893; called by muse, mutect2, varscan2
- MGA | c.1445A>G p.K482R | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99580813; called by muse, mutect2, varscan2
- MGA | c.6125G>C p.C2042S (on ENST00000219905 / NM_001164273.1; = p.C1833S on NM_001080541.2) | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV99580817; called by muse, mutect2, varscan2
- MMP7 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99497119; called by muse, mutect2
- MOV10 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs989775366, CM137440, COSV100659369; called by muse, mutect2, varscan2
- MPLKIP | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100003492; called by muse, mutect2, varscan2
- MTMR11 | c.1271del p.G424Efs*52 (on ENST00000439741 / NM_001145862.2; = p.G352Efs*52 on NM_181873.3) | Frame Shift Del (DEL) | VAF 88/306 reads (29%) | catalogued as COSV54965506; called by mutect2, pindel, varscan2
- MTRR | c.1580T>C p.V527A (on ENST00000264668; = p.V500A on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99241931; called by muse, mutect2, varscan2
- MUS81 | c.503C>A p.A168D | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100337317; called by muse, mutect2, varscan2
- MYCBP2 | c.3635C>T p.S1212L (on ENST00000357337; = p.S1250L on NM_015057.5) | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100631132, COSV62014151; called by muse, mutect2, varscan2
- MYH6 | c.1976A>T p.K659M | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100676832; called by muse, mutect2, varscan2
- MYO3A | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV99780725; called by muse, mutect2, varscan2
- MYO5A | c.5254C>A p.Q1752K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as COSV100697945, COSV62560040; called by muse, varscan2
- MYT1L | c.1112C>A p.T371K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.388); catalogued as COSV101221064, COSV67719184; called by muse, mutect2, varscan2
- NAV3 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.598); catalogued as COSV57106112; called by muse, mutect2, varscan2
- NCAN | c.3647G>T p.G1216V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53046554, COSV99387878; called by muse, mutect2, varscan2
- NCOA1 | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99946680; called by muse, mutect2, varscan2
- NCOR2 | c.1824G>C p.E608D | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100657704; called by muse, mutect2, varscan2
- NETO2 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as rs757500477, COSV100292537, COSV57452356; called by muse, mutect2, varscan2
- NFATC2 | c.2462G>T p.R821L | Missense Mutation (SNP) | VAF 165/233 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs373570203, COSV101044397; called by muse, mutect2, varscan2
- NLRP10 | c.1157T>C p.M386T | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs756879833, COSV100149858; called by muse, mutect2, varscan2
- NOX4 | c.914G>C p.S305T | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV99631370; called by muse, mutect2, varscan2
- NPHP4 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100977072; called by muse, mutect2
- NR0B2 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99575054; called by muse, mutect2, varscan2
- NRCAM | c.817C>A p.P273T (on ENST00000379028 / NM_001371124.1; = p.P267T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100695142; called by muse, mutect2, varscan2
- NRXN1 | c.3711C>A p.Y1237* | Nonsense Mutation (SNP) | VAF 152/397 reads (38%) | catalogued as COSV100640515; called by muse, mutect2, varscan2
- NTM | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV100869112; called by muse, mutect2
- NUDT17 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100566824; called by muse, mutect2, varscan2
- OR10H5 | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100454773; called by muse, mutect2, varscan2
- OR4K14 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100520484; called by muse, mutect2, varscan2
- OR5A1 | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100118435, COSV57377990; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1606C>T p.R536* (on ENST00000259318 / NM_001136562.3; = p.R767* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as rs776365046, COSV99395513; called by muse, mutect2, varscan2
- PAPPA2 | c.3277G>C p.A1093P | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100868381; called by muse, varscan2
- PAPPA2 | c.3352G>T p.G1118W | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62812056; called by muse, varscan2
- PARPBP | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV100268294; called by muse, mutect2, varscan2
- PCDH15 | c.4588G>A p.V1530I | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.897); catalogued as COSV100905281; called by muse, mutect2, varscan2
- PCDH7 | c.2645T>A p.I882N | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100688531; called by muse, mutect2, varscan2
- PCDHB11 | c.22A>C p.T8P | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs782508816, COSV53378648, COSV99504736; called by muse, varscan2
- PCDHB16 | c.1643G>T p.R548L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1390176922; called by mutect2, varscan2
- PCDHGA9 | c.592C>G p.R198G | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.087); catalogued as COSV99542932; called by muse, mutect2, varscan2
- PCDHGB1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV53942197; called by muse, mutect2, varscan2
- PHF14 | c.2408A>G p.Q803R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV101301835; called by muse, mutect2, varscan2
- PHKG2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.162); catalogued as rs1298783918, COSV60313540; called by muse, mutect2
- PLBD2 | c.1002G>T p.W334C | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99785318; called by muse, mutect2, varscan2
- PLCB4 | c.2563A>T p.M855L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99596290; called by muse, mutect2, varscan2
- PNN | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV99397318; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV100544391; called by muse, mutect2, varscan2
- POLQ | c.4489G>T p.D1497Y | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV99952600; called by muse, mutect2, varscan2
- POTEF | c.1990A>C p.T664P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV100665147; called by muse, mutect2
- PPP1R21 | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.307); catalogued as COSV99682368; called by muse, mutect2, varscan2
- PPP1R21 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99682373; called by muse, mutect2, varscan2
- PPP1R3A | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV99493606; called by muse, mutect2, varscan2
- PPP4R4 | c.2330A>T p.N777I | Missense Mutation (SNP) | VAF 79/103 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as COSV100428856; called by muse, mutect2, varscan2
- PROKR1 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1558580435, COSV100375652; called by muse, mutect2, varscan2
- PROSER1 | c.2623G>T p.G875C | Missense Mutation (SNP) | VAF 107/176 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100612923; called by muse, mutect2, varscan2
- PRSS16 | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100041874; called by muse, mutect2, varscan2
- PRTG | c.2530G>C p.D844H | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV101221442; called by muse, mutect2, varscan2
- PTPN14 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.575); catalogued as rs760793358, COSV100872826; called by muse, mutect2, varscan2
- RAI1 | c.1307C>G p.T436R | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99884622; called by muse, mutect2, varscan2
- RAPGEF5 | c.895C>G p.P299A (on ENST00000401957 / NM_001367602.2; = p.P602A on NM_012294.5) | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV100687527; called by muse, mutect2, varscan2
- RBBP6 | c.2260C>T p.H754Y | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as rs543399143, COSV100154780; called by muse, mutect2, varscan2
- RELN | c.2503T>A p.F835I | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100634349; called by muse, mutect2, varscan2
- RIPK3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 99/245 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs183066662, COSV53476565; called by muse, mutect2, varscan2
- ROBO2 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV100168668, COSV59906515; called by muse, mutect2, varscan2
- RTP5 | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100574779; called by muse, mutect2, varscan2
- SATB2 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV99612037; called by muse, mutect2, varscan2
- SDR39U1 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); catalogued as COSV99249949; called by muse, mutect2, varscan2
- SLC10A2 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV55360977, COSV99808140; called by muse, mutect2, varscan2
- SLC17A3 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100399336; called by muse, mutect2, varscan2
- SLC6A15 | c.1628C>A p.A543D | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99881282; called by muse, mutect2, varscan2
- SLC9A8 | c.1575G>C p.K525N | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100846288; called by muse, mutect2, varscan2
- SLIT3 | c.3193G>T p.G1065C | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100268896; called by muse, mutect2, varscan2
- SMARCD2 | c.1024A>C p.N342H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.317); catalogued as COSV99856552; called by muse, mutect2, varscan2
- SMCHD1 | c.3539G>A p.G1180E | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99862152; called by muse, mutect2, varscan2
- SMG8 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99958969; called by muse, mutect2, varscan2
- SMPD4 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100302624; called by muse, mutect2, varscan2
- SND1 | c.2304+1G>A p.X768_splice | Splice Site (SNP) | VAF 31/112 reads (28%) | catalogued as rs1283029806, COSV61236891; called by muse, mutect2, varscan2
- SNTA1 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 88/142 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368660364, CM099804; called by muse, mutect2, varscan2
- SORCS3 | c.885C>G p.F295L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100865460; called by muse, mutect2, varscan2
- SPANXB1 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1375388891; called by muse, mutect2, varscan2
- ST6GAL2 | c.134T>C p.F45S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | PolyPhen benign (0.255); catalogued as COSV100868170; called by muse, mutect2, varscan2
- STARD3NL | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99151601; called by muse, mutect2, varscan2
- SULT1A2 | c.276G>A p.G92= | Splice Region (SNP) | VAF 61/157 reads (39%) | catalogued as rs1246417986, COSV100187283; called by muse, mutect2, varscan2
- SULT4A1 | c.249C>G p.D83E | Missense Mutation (SNP) | VAF 104/135 reads (77%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.785); catalogued as COSV50781448, COSV99970670; called by muse, mutect2, varscan2
- SYNPO2 | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV100206112; called by muse, mutect2, varscan2
- TAS2R41 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101281505; called by muse, mutect2, varscan2
- TCP10L | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.067); catalogued as COSV100291963; called by muse, mutect2, varscan2
- TENM2 | c.1019C>G p.T340S (on ENST00000518659 / NM_001122679.2; = p.T149S on NM_001080428.3) | Missense Mutation (SNP) | VAF 85/122 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV101319197; called by muse, mutect2, varscan2
- TET3 | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as COSV99996512; called by muse, mutect2, varscan2
- TGIF2LX | c.299G>T p.W100L | Missense Mutation (SNP) | VAF 100/129 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52215586, COSV99383470; called by muse, mutect2, varscan2
- TIAM1 | c.1838A>T p.Q613L | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV99737529; called by muse, mutect2, varscan2
- TIMD4 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 248/342 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99192767; called by muse, mutect2, varscan2
- TKTL2 | c.528G>C p.L176F | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54920870; called by muse, mutect2, varscan2
- TMEM70 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV100384172; called by muse, mutect2, varscan2
- TMEM74B | c.53A>T p.E18V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV101121981; called by muse, mutect2, varscan2
- TNRC6A | c.5788G>T p.G1930C | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170321; called by muse, mutect2, varscan2
- TPD52L1 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV100509401; called by muse, mutect2, varscan2
- TRHDE | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as COSV99671762; called by muse, mutect2, varscan2
- TRIM48 | c.400T>C p.S134P | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101338327; called by muse, mutect2, varscan2
- TSHR | c.1469C>A p.T490K | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM0910980, COSV53328425, COSV99992402; called by muse, mutect2, varscan2
- TSPEAR | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554762; called by muse, mutect2, varscan2
- TTC6 | c.548G>A p.G183E (on ENST00000267368; = p.G1549E on NM_001310135.3) | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99942107; called by mutect2, varscan2
- TTN | c.17567G>T p.S5856I (on ENST00000591111; = p.S4929I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/123 reads (44%) | PolyPhen probably damaging (0.997); catalogued as COSV100622509; called by muse, mutect2, varscan2
- TTN | c.10988C>A p.T3663N (on ENST00000591111; = p.T3617N on NM_003319.4) | Missense Mutation (SNP) | VAF 69/131 reads (53%) | catalogued as COSV100622513; called by muse, mutect2, varscan2
- TTN | c.4758C>A p.D1586E (on ENST00000591111; = p.D1540E on NM_003319.4) | Missense Mutation (SNP) | VAF 50/195 reads (26%) | PolyPhen probably damaging (0.996); catalogued as COSV100622519; called by muse, mutect2, varscan2
- UBE2NL | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 177/205 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs782130012; called by muse, mutect2, varscan2
- UGT2B28 | c.85T>A p.W29R | Missense Mutation (SNP) | VAF 164/195 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100158944; called by muse, mutect2, varscan2
- WDR3 | c.2017-1G>T p.X673_splice | Splice Site (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100309893; called by muse, mutect2
- WDR6 | c.1028A>G p.K343R | Missense Mutation (SNP) | VAF 103/144 reads (72%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100556624; called by muse, mutect2, varscan2
- WNK3 | c.4935G>C p.M1645I | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100671833; called by muse, mutect2, varscan2
- XPO7 | c.1796A>T p.N599I | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99381758; called by muse, mutect2, varscan2
- XRN1 | c.3280G>A p.G1094R | Missense Mutation (SNP) | VAF 86/105 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99378602; called by muse, mutect2, varscan2
- ZBTB20 | c.644C>G p.T215S (on ENST00000474710 / NM_001164342.2; = p.T142S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/154 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV100614561; called by muse, mutect2, varscan2
- ZC3H12C | c.2402A>G p.Q801R | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV99585195; called by muse, mutect2, varscan2
- ZC3H13 | c.46A>G p.I16V | Missense Mutation (SNP) | VAF 86/123 reads (70%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs774554070, COSV99668618; called by muse, mutect2, varscan2
- ZDBF2 | c.2188A>C p.N730H | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100985205; called by muse, mutect2, varscan2
- ZFHX4 | c.4234C>A p.L1412I | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99265621; called by muse, mutect2, varscan2
- ZFP28 | c.826T>G p.L276V | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100019738; called by muse, mutect2, varscan2
- ZNF676 | c.833T>C p.I278T (on ENST00000650058; = p.I246T on NM_001001411.3) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV101236289; called by muse, varscan2
- ZNF804A | c.1482G>T p.M494I | Missense Mutation (SNP) | VAF 111/198 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100169189; called by muse, mutect2, varscan2
- ZP4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/33 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs1210629397, COSV100850734; called by muse, mutect2, varscan2
- ALCAM | c.1475del p.E492Gfs*4 | Frame Shift Del (DEL) | VAF 40/80 reads (50%) | called by mutect2, pindel, varscan2
- ALDH3A2 | c.1014_1019del p.I339_V340del | In Frame Del (DEL) | VAF 26/48 reads (54%) | called by pindel, varscan2
- AMY2A | c.706T>A p.W236R | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); called by mutect2, varscan2
- CRYBG2 | c.1007G>T p.S336I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 119/285 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ITPRID1 | c.661del p.D221Mfs*23 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- PKDREJ | c.5572_5574del p.Y1858del | In Frame Del (DEL) | VAF 111/127 reads (87%) | called by mutect2, pindel, varscan2
- SPAG17 | c.3193del p.V1065* | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- TPO | c.518del p.L173Rfs*36 | Frame Shift Del (DEL) | VAF 57/193 reads (30%) | called by mutect2, pindel, varscan2
- TYMP | c.434_437dup p.G147Tfs*12 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel
- VCX | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- VCX2 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.439); called by mutect2, varscan2
- XIRP2 | c.7492del p.C2498Afs*46 (on ENST00000628543; = p.C2673Afs*46 on NM_152381.6) | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- ABCA9 | c.213T>C p.F71= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV100383333; called by muse, mutect2, varscan2
- AC068580.4 | c.999C>T p.S333= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as rs755867394, COSV99362474; called by muse, mutect2, varscan2
- ADAMTS12 | c.1725G>A p.K575= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100711432, COSV61274452; called by muse, mutect2, varscan2
- AKAP9 | c.6522G>A p.R2174= (on ENST00000359028; = p.R2142= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV100662743; called by muse, mutect2, varscan2
- AMER3 | c.438C>T p.I146= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100366757, COSV58469890; called by muse, mutect2, varscan2
- ANK2 | c.3750T>C p.G1250= | Silent (SNP) | VAF 75/163 reads (46%) | catalogued as COSV100003065; called by muse, mutect2, varscan2
- ASH1L | c.1194A>T p.G398= | Silent (SNP) | VAF 91/286 reads (32%) | catalogued as COSV100853535; called by muse, mutect2, varscan2
- ATP13A5 | c.2004G>T p.G668= | Silent (SNP) | VAF 106/144 reads (74%) | catalogued as COSV100665464; called by muse, mutect2, varscan2
- BMP3 | c.60G>T p.A20= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs775730553, COSV51082303, COSV99261880; called by muse, mutect2, varscan2
- BTBD11 | c.3285C>T p.H1095= (on ENST00000280758 / NM_001018072.2; = p.H632= on NM_001017523.2) | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV99776515; called by muse, mutect2, varscan2
- CCDC47 | c.903C>T p.I301= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as COSV99854265; called by muse, mutect2, varscan2
- CD300LB | c.504C>T p.A168= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs748812930, COSV100075504; called by muse, mutect2, varscan2
- CD93 | c.48C>A p.T16= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99849416; called by muse, varscan2
- CDH8 | c.1338G>T p.G446= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100183308; called by muse, mutect2, varscan2
- CDH9 | c.1770C>A p.A590= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV99149714; called by muse, mutect2, varscan2
- DGKK | c.2298C>A p.A766= | Silent (SNP) | VAF 47/58 reads (81%) | catalogued as rs1557224961, COSV101053132; called by muse, mutect2, varscan2
- DNAJC6 | c.2373C>T p.F791= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV99675352; called by muse, mutect2, varscan2
- DPP6 | c.1201C>A p.R401= (on ENST00000377770 / NM_001364500.2; = p.R339= on NM_001936.5) | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100127017, COSV100127633; called by muse, mutect2, varscan2
- EP400 | c.4536G>T p.P1512= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV100201830, COSV57764468; called by muse, mutect2, varscan2
- FBXL18 | c.2019C>T p.P673= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as rs374847105; called by muse, mutect2, varscan2
- GDF5 | c.360G>T p.R120= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as COSV100976914; called by muse, mutect2
- GPR174 | c.702C>T p.T234= | Silent (SNP) | VAF 62/75 reads (83%) | catalogued as COSV99338312; called by muse, mutect2, varscan2
- HFM1 | c.3276C>G p.V1092= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99646447; called by muse, mutect2, varscan2
- HLX | c.979C>A p.R327= | Silent (SNP) | VAF 45/54 reads (83%) | catalogued as COSV100854589; called by muse, mutect2, varscan2
- HMCN1 | c.5691A>C p.T1897= | Silent (SNP) | VAF 108/126 reads (86%) | catalogued as COSV99632863; called by muse, mutect2, varscan2
- HNRNPLL | c.444T>C p.S148= | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as COSV99696625; called by muse, mutect2, varscan2
- IL7R | c.1161C>T p.S387= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs139678300, COSV57412004; called by muse, mutect2, varscan2
- KALRN | c.4050G>A p.K1350= | Silent (SNP) | VAF 85/115 reads (74%) | catalogued as COSV99566156; called by muse, mutect2, varscan2
- KBTBD6 | c.1773G>A p.R591= | Silent (SNP) | VAF 69/101 reads (68%) | catalogued as COSV101068828, COSV65272033; called by muse, mutect2, varscan2
- KCNA5 | c.1662G>C p.R554= | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as COSV52905024, COSV99364053; called by muse, mutect2, varscan2
- LAMA5 | c.4089G>A p.V1363= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99441284; called by muse, mutect2, varscan2
- LELP1 | c.42T>C p.T14= | Silent (SNP) | VAF 61/204 reads (30%) | catalogued as COSV100907354; called by muse, mutect2, varscan2
- LILRB5 | c.918G>T p.S306= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV100300648; called by muse, mutect2, varscan2
- LRRC6 | c.171G>A p.G57= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99138317; called by muse, mutect2, varscan2
- LRRC71 | c.832C>T p.L278= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100504082; called by muse, mutect2, varscan2
- LTBP4 | c.312A>G p.R104= (on ENST00000308370 / NM_001042544.1; = p.R67= on NM_003573.2) | Silent (SNP) | VAF 74/110 reads (67%) | catalogued as rs1174432387, COSV99198929; called by muse, mutect2, varscan2
- MGAT4C | c.84C>T p.F28= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs138787902, COSV100152987, COSV59832339; called by muse, mutect2, varscan2
- MYBPH | c.1188C>A p.G396= | Silent (SNP) | VAF 24/30 reads (80%) | catalogued as COSV99704621; called by muse, mutect2, varscan2
- MYLK3 | c.1974G>T p.G658= | Silent (SNP) | VAF 65/130 reads (50%) | catalogued as COSV101189166; called by muse, mutect2, varscan2
- MYO3B | c.2427G>T p.L809= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV100511109; called by muse, mutect2, varscan2
- NLRP5 | c.1920C>T p.L640= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as rs771082914, COSV101173812; called by muse, mutect2, varscan2
- NPTX2 | c.955C>A p.R319= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as COSV99675022; called by muse, mutect2, varscan2
- NUP188 | c.3816G>T p.R1272= | Silent (SNP) | VAF 47/68 reads (69%) | catalogued as COSV101001439; called by muse, mutect2, varscan2
- NUP214 | c.1179A>T p.S393= | Silent (SNP) | VAF 75/98 reads (77%) | catalogued as COSV100845362; called by muse, mutect2, varscan2
- OR4A15 | c.183G>T p.L61= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as COSV100124262; called by muse, mutect2, varscan2
- OR4K5 | c.12C>A p.S4= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV100262508; called by muse, varscan2
- OR5M3 | c.531T>C p.C177= | Silent (SNP) | VAF 83/200 reads (42%) | catalogued as COSV100392623; called by muse, mutect2, varscan2
- ORC5 | c.831G>A p.Q277= | Silent (SNP) | VAF 61/177 reads (34%) | catalogued as COSV99857215; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1245G>T p.R415= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1204932936, COSV100543985; called by muse, mutect2, varscan2
- PODN | c.1032C>T p.S344= (on ENST00000395871; = p.S296= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/164 reads (27%) | catalogued as rs565662939, COSV100439718; called by muse, mutect2, varscan2
- POU2AF1 | c.534G>A p.P178= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs752000372, COSV101260684; called by muse, mutect2, varscan2
- PRPH2 | c.7C>T p.L3= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100028180; called by muse, mutect2
- RAP2B | c.177G>A p.A59= | Silent (SNP) | VAF 125/166 reads (75%) | catalogued as COSV100059019; called by muse, mutect2, varscan2
- RBBP9 | c.342C>T p.F114= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100464113; called by muse, varscan2
- REG1A | c.354G>A p.L118= | Silent (SNP) | VAF 66/225 reads (29%) | catalogued as COSV99286905; called by muse, mutect2, varscan2
- RTL8A | c.27G>A p.K9= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as rs777430132, COSV100887742; called by muse, mutect2
- SFN | c.402G>A p.V134= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV100212858; called by muse, mutect2, varscan2
- SLC18A2 | c.858C>G p.T286= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV100041870; called by muse, mutect2, varscan2
- SLC25A45 | c.150G>A p.E50= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV53685451; called by muse, mutect2, varscan2
- SLC6A2 | c.1416G>T p.L472= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV99574292; called by muse, mutect2, varscan2
- SPATA31A3 | c.2760C>A p.G920= | Silent (SNP) | VAF 15/25 reads (60%) | called by mutect2, varscan2
- SPOCK3 | c.813A>T p.S271= | Silent (SNP) | VAF 113/147 reads (77%) | catalogued as COSV100693569; called by muse, mutect2, varscan2
- STAB2 | c.252C>T p.L84= | Silent (SNP) | VAF 125/240 reads (52%) | catalogued as COSV101186163; called by muse, mutect2, varscan2
- TAS2R16 | c.375G>A p.L125= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV99972305; called by muse, mutect2, varscan2
- TNR | c.3318G>T p.T1106= | Silent (SNP) | VAF 65/84 reads (77%) | catalogued as COSV99689490, COSV99690662; called by muse, mutect2, varscan2
- UBA1 | c.954G>T p.T318= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as COSV60113881; called by muse, mutect2, varscan2
- VWA7 | c.834C>T p.L278= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV100989951; called by muse, mutect2, varscan2
- WDR37 | c.27G>T p.S9= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as COSV99580008; called by muse, mutect2, varscan2
- WT1 | c.1488C>A p.T496= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV100188584; called by muse, mutect2, varscan2
- ZBTB16 | c.357G>A p.L119= | Silent (SNP) | VAF 48/65 reads (74%) | catalogued as COSV100251841; called by muse, mutect2, varscan2
- ZDBF2 | c.1758T>C p.D586= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100985202; called by muse, mutect2, varscan2
- ZMYND12 | c.942C>T p.V314= | Silent (SNP) | VAF 44/204 reads (22%) | catalogued as COSV65342665; called by muse, mutect2
- ZNF804A | c.3513C>A p.I1171= | Silent (SNP) | VAF 43/185 reads (23%) | catalogued as COSV100169194; called by muse, mutect2, varscan2
- ZNF827 | c.1242G>A p.K414= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as COSV101061557; called by muse, mutect2, varscan2
- AIRE | c.880-28C>G | Intron (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- COL5A1 | c.5136+96T>A | Intron (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65818C>A | Intron (SNP) | VAF 319/443 reads (72%) | catalogued as COSV54663888, COSV99718044; called by muse, mutect2, varscan2
- FBXL21P | n.920C>G | RNA (SNP) | VAF 44/64 reads (69%) | catalogued as COSV99778404; called by muse, mutect2, varscan2
- MFRP | chr11:119344923 C>A | 5'Flank (SNP) | VAF 26/33 reads (79%) | catalogued as COSV100793506; called by muse, mutect2, varscan2
- PCDHA5 | c.2352+18A>G | Intron (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100972461; called by muse, mutect2, varscan2
- RGS3 | c.415+1623G>A | Intron (SNP) | VAF 44/52 reads (85%) | catalogued as rs1454704433, COSV100465635; called by muse, mutect2, varscan2
- RPSA | c.498+145C>G | Intron (SNP) | VAF 86/106 reads (81%) | catalogued as COSV100088230, COSV57191536; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1648A>T | Intron (SNP) | VAF 137/199 reads (69%) | catalogued as COSV100314620; called by muse, mutect2, varscan2
- TMEM99 | n.798C>G | RNA (SNP) | VAF 95/365 reads (26%) | catalogued as COSV100054163, COSV56982717; called by muse, mutect2, varscan2
